Somatic mutation profile of tumor specimen 0DVZ1E from CCDI case PBCLXY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 13.4 years (4,887 days).
Specimen 0DVZ1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18d07f1e-8d3a-46fd-9987-fc4171467d7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/837019be-95d2-4f69-82eb-0bb34a18c472

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 3, Silent 3, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3149G>A p.G1050D | Missense Mutation (SNP) | VAF 312/770 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121912914, CM000356, CM890039; ClinVar: pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 242/930 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 415/486 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CMA1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 241/565 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as rs755977857, COSV51625626; called by muse, mutect2, varscan2
- HNF1A | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as rs774637975, CM064303, COSV99982822; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KCNJ14 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 131/547 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs770005092, COSV53520013; called by muse, mutect2, varscan2
- NRXN2 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 184/312 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs759395634; called by muse, mutect2, varscan2
- PCDHB3 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV50570221; called by muse, mutect2, varscan2
- PDE4D | c.623G>A p.R208Q (on ENST00000340635 / NM_001104631.2; = p.R72Q on NM_006203.4) | Missense Mutation (SNP) | VAF 140/766 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs926956807, COSV58945115; called by muse, mutect2, varscan2
- RNGTT | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 510/1105 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs370993760, COSV55646826; called by muse, mutect2, varscan2
- SHROOM3 | c.2998C>T p.P1000S | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.172); catalogued as COSV56024643; called by muse, mutect2, varscan2
- ZFAND4 | c.183A>G p.E61= | Splice Region (SNP) | VAF 204/241 reads (85%) | catalogued as COSV58896892; called by muse, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 33/1060 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- GRN | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 154/553 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT16 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 131/389 reads (34%) | called by muse, mutect2, varscan2
- TMC3 | c.2661C>A p.Y887* | Nonsense Mutation (SNP) | VAF 178/814 reads (22%) | called by muse, mutect2, varscan2
- CUBN | c.5517C>T p.S1839= | Silent (SNP) | VAF 208/1069 reads (19%) | catalogued as rs754868648, COSV64727422; called by muse, mutect2, varscan2
- ITIH1 | c.39C>T p.C13= | Silent (SNP) | VAF 208/470 reads (44%) | called by muse, mutect2, varscan2
- JPH2 | c.681G>A p.L227= | Silent (SNP) | VAF 152/364 reads (42%) | called by muse, mutect2, varscan2
- ASB1 | c.50-55G>T | Intron (SNP) | VAF 175/337 reads (52%) | called by muse, mutect2, varscan2
- RAVER1 | c.1431+245G>A | Intron (SNP) | VAF 245/534 reads (46%) | catalogued as rs577409503; called by muse, mutect2, varscan2
- SELENOW | c.54+47G>A | Intron (SNP) | VAF 226/487 reads (46%) | catalogued as rs1448994855; called by muse, mutect2, varscan2
